Surgical pathology report (de-identified scan), TCGA case TCGA-UT-A97Y, project TCGA-MESO (Mesothelioma), tissue source site Asbestos Diseases Research Institute, specimen TCGA-UT-A97Y-01A (Primary Tumor).

Copy Sent to

CLINICAL INFORMATION

Mesothelioma.

MACROSCOPIC DESCRIPTION

Labelled "Right parietal pleura".

Specimen consists of multiple pieces of cream to grey and haemorrhagic fibrous and membranous tissue measuring from 13x7x6mm up to 30x18x8mm.

MICROSCOPIC DESCRIPTION

The specimen consists of portions of pleura which show abundant surface fibrinous exudate showing transition to a zone of fibrosis containing a malignant infiltrate. The malignant cells are arranged in poorly cohesive clusters, cords and singly in a background of fibrosis. The cells have enlarged nuclei with focally prominent nucleoli and a variable amount of eosinophilic to slightly vacuolated cytoplasm. There are psammoma bodies associated with the infiltrate. PAS diastase stain shows

Immunohistochemistry shows the tumour is strongly positive for CK7, weakly positive for CK20, positive for 34Beta12, strongly positive for calretinin and weakly positive for CA125. TTF-1 is negative.

The findings are consistent with malignant mesothelioma, epithelial type.

CONCLUSION

RIGHT PARIETAL PLEURAL BIOPSY
-- MALIGNANT MESOTHELIOMA, EPITHELIAL TYPE.

ICD-O-3
Mesothelioma, epithelioid,
malignant 985213
Site: @Pleura NOS
C38.4
JW 1/23/14

Source: NCI Genomic Data Commons file 52aba616-63ac-4574-a9c5-754eeb8d9a60 (TCGA-UT-A97Y.81859C99-1011-4421-A5E3-87844EB925F0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).